Surgical pathology report (de-identified scan), TCGA case TCGA-Z5-AAPL, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Cureline, specimen TCGA-Z5-AAPL-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Pancreatic cancer

Date of procurement: (mm/dd/yyyy)

Sample:

Gross description: Pancreas (body and tail) 3.5x 2x1.5 cm. Discovered tumor mass in pancreas. Section reveals dense, grayish-white surface. Tumor infiltrated pancreatic capsule and adjacent adipose tissue. Adjacent adipose tissue contains 9 lymphatic nodes 2cm – 1cm in diameter. Soft, pink-gray appearance.

Microscopic description:

- 1) Histology consistent with poorly differentiated ductal adenocarcinoma (G1), infiltrating pancreas, adjacent adipose tissue with multiple nests of intra- and extra-pancreatic invasion.
- 2) All 9 lymph nodes are negative
- 3) Pancreas shows signs of chronic inflammation.

Final diagnosis: Low grade pancreatic adenocarcinoma, ductal type, grade 1.

ICD-6-3

Adenocarcinoma, duct NOS 8000/3

Site: Pancreas NOS C25.9

4/22/14

Confidential

Source: NCI Genomic Data Commons file 36e8f19f-03c8-49fb-8bcc-ae92128c372f (TCGA-Z5-AAPL.10A49855-26E8-47AB-B7A8-941737E26C1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).